Somatic mutation profile of tumor specimen TCGA-S9-A6WI-01A (aliquot TCGA-S9-A6WI-01A-21D-A33T-08) from TCGA case TCGA-S9-A6WI, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 56.4 years (20,609 days).
Specimen TCGA-S9-A6WI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55262b27-16bb-44d8-a270-fc21667038e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WI-10A (Blood Derived Normal), aliquot TCGA-S9-A6WI-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d0badb7-988c-4f25-bfd3-6f0a88fee8d3

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 14, Silent 2, Splice Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 23/214 reads (11%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CASKIN1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100623720; called by muse, mutect2
- DKKL1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as rs1315428412, COSV99678562; called by muse, mutect2, varscan2
- FAM83G | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1197063594, COSV100524689; called by muse, mutect2, varscan2
- FREM2 | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs762195899, COSV99746089; called by muse, mutect2, varscan2
- HTR2C | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.889); catalogued as COSV99347762; called by muse, mutect2, varscan2
- MED12L | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV56379028; called by muse, mutect2, varscan2
- PACRGL | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs373074413; called by muse, mutect2, varscan2
- PKD1 | c.10894G>A p.E3632K (on ENST00000262304 / NM_001009944.3; = p.E3631K on NM_000296.4) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368279785, COSV99236923; called by muse, mutect2
- PLEKHG5 | c.1911+1G>A p.X637_splice (on ENST00000400915 / NM_001042663.3; = p.X600_splice on NM_020631.6) | Splice Site (SNP) | VAF 9/91 reads (10%) | catalogued as COSV100555836; called by muse, mutect2, varscan2
- PSME1 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.558); catalogued as COSV99245950; called by muse, mutect2, varscan2
- RALGAPB | c.4367A>T p.H1456L | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs976409868, COSV99484554; called by muse, mutect2
- RTL5 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV101029814; called by muse, mutect2
- SPAG9 | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100004286; called by muse, mutect2, varscan2
- KMT2E | c.1288_1293del p.I430_Y431del | In Frame Del (DEL) | VAF 25/180 reads (14%) | called by mutect2, pindel, varscan2
- LGR4 | c.1065_1066del p.I355Mfs*7 | Frame Shift Del (DEL) | VAF 23/204 reads (11%) | called by mutect2, pindel, varscan2
- ZNF517 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2
- NEK8 | c.135G>A p.R45= | Silent (SNP) | VAF 11/145 reads (8%) | catalogued as COSV99261397; called by muse, mutect2
- TRAIP | c.921G>A p.R307= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV58913625; called by muse, mutect2, varscan2
